Somatic mutation profile of tumor specimen TCGA-VN-A88M-01A (aliquot TCGA-VN-A88M-01A-11D-A34U-08) from TCGA case TCGA-VN-A88M, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.2 years (20,157 days).
Specimen TCGA-VN-A88M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28756420-1959-4cf7-a8c6-4dfde98e8d28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88M-10A (Blood Derived Normal), aliquot TCGA-VN-A88M-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/167a1b72-8ee4-4bfa-b6f9-3f78efaec643

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCOCO1 | c.1423C>A p.L475M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as COSV100017333; called by muse, mutect2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2
- KCNH3 | c.310+1G>T p.X104_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99235222; called by muse, mutect2, varscan2
- MED13 | c.5489G>A p.R1830Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377382016; called by muse, mutect2, varscan2
- MMP16 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs147772248; called by mutect2, varscan2
- PPAT | c.1437A>T p.K479N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99947254; called by muse, mutect2
- RNF213 | c.11470C>T p.R3824C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768762468, COSV60390893; called by muse, mutect2, varscan2
- RPL10 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.299); catalogued as COSV99185942; called by muse, mutect2
- SIRPA | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100605182; called by muse, mutect2, varscan2
- SLC5A5 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV99715038; called by muse, mutect2, varscan2
- ZNF763 | c.1099C>T p.P367S (on ENST00000358987 / NM_001367172.2; = p.P370S on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1568312250, COSV100676101; called by muse, mutect2, varscan2
- KNDC1 | c.3963C>T p.C1321= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs372197149; called by muse, mutect2, varscan2
- LRP1B | c.8916C>T p.C2972= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1486382997, COSV67214457; called by muse, mutect2, varscan2
- PRAMEF20 | c.45G>T p.R15= | Silent (SNP) | VAF 22/296 reads (7%) | called by muse, mutect2
- ZNF700 | c.1968A>G p.A656= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99583527; called by muse, mutect2
